Somatic mutation profile of tumor specimen ALCH-B28T-TTP1-A (aliquot ALCH-B28T-TTP1-A-1-0-D-A775-36) from ALCHEMIST case ALCH-B28T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.8 years (23,296 days).
Specimen ALCH-B28T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e67a229-d025-442c-81f1-e7e304c04522.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B28T-NB1-A (Blood Derived Normal), aliquot ALCH-B28T-NB1-A-1-0-D-A775-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/971d6857-b1a3-44d5-8e57-9a725aba3e6a

The open-access MAF lists 197 somatic variants for this specimen: 136 protein-altering or splice-affecting, 42 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 42, Intron 12, Nonsense Mutation 11, 3'UTR 3, 5'UTR 2, Splice Site 2, Frame Shift Del 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2582T>G p.L861R | Missense Mutation (SNP) | VAF 120/1088 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913444, COSV51766344, COSV51766618; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 70/758 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ALG10B | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 35/964 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV58145320; called by muse, mutect2
- ALOX5 | c.1897G>C p.E633Q | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.667); catalogued as COSV100980100; called by muse, mutect2
- ANKS1B | c.2962C>G p.L988V | Missense Mutation (SNP) | VAF 60/628 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV59125876; called by muse, mutect2
- CAVIN4 | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 24/359 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as rs772843878; called by muse, mutect2
- CLPTM1 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.64); catalogued as rs150314527; called by muse, mutect2
- CRB1 | c.1933G>T p.D645Y | Missense Mutation (SNP) | VAF 123/1307 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218091828, COSV66329056; called by muse, mutect2
- DAPK1 | c.3223G>T p.D1075Y | Missense Mutation (SNP) | VAF 44/341 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV63784132; called by muse, mutect2, varscan2
- DOCK10 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99288052; called by muse, mutect2
- DST | c.9142G>C p.E3048Q | Missense Mutation (SNP) | VAF 27/695 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as COSV55047257; called by muse, mutect2
- EGFR | c.2512C>G p.L838V | Missense Mutation (SNP) | VAF 87/783 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs864621996, COSV51791922, COSV51866622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELP2 | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 43/586 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as rs780354979; called by muse, mutect2
- ERG | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 66/637 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV55740391; called by muse, mutect2, varscan2
- FAM83B | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs867224522, COSV60923974; called by muse, mutect2
- FAT3 | c.13259C>G p.P4420R | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.775); catalogued as rs1442123582; called by muse, mutect2
- FERMT1 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 45/427 reads (11%) | catalogued as COSV54097517; called by muse, mutect2, varscan2
- FLG2 | c.3328G>T p.G1110C | Missense Mutation (SNP) | VAF 30/714 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.409); catalogued as rs1260471834; called by muse, mutect2
- FRAS1 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 44/586 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201927256, COSV53647961; called by muse, mutect2
- GC | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.766); catalogued as COSV56738125, COSV99909555; called by muse, mutect2
- GLP2R | c.1379C>G p.S460* | Nonsense Mutation (SNP) | VAF 20/200 reads (10%) | catalogued as COSV99302085; called by muse, mutect2
- IGFALS | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs778042723; called by muse, mutect2
- KCNH2 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs748762712, COSV51238041; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP1B | c.4227G>A p.M1409I | Missense Mutation (SNP) | VAF 24/658 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV101260064; called by muse, mutect2
- LRRTM1 | c.944T>G p.L315R | Missense Mutation (SNP) | VAF 64/530 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.329); catalogued as COSV99702890; called by mutect2, varscan2
- MAGEB6 | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 22/421 reads (5%) | catalogued as COSV66872464; called by muse, mutect2
- NHSL2 | c.139G>A p.E47K (on ENST00000510661; = p.E413K on NM_001013627.2) | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs747748396; called by muse, mutect2
- PANX3 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 24/383 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52511633; called by muse, mutect2
- PCDHA2 | c.1893C>G p.I631M | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1554120158; called by muse, mutect2
- PCDHA9 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 30/588 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as rs1554144012; called by muse, mutect2
- PLEKHG3 | c.3107C>T p.S1036L (on ENST00000394691; = p.S1092L on NM_001308147.2) | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as rs528793635, COSV99906274; called by muse, mutect2
- PODN | c.725G>A p.R242K (on ENST00000395871; = p.R194K on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.395); catalogued as COSV100439442; called by muse, mutect2
- PPFIA2 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 19/666 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV61058997; called by muse, mutect2
- PROKR2 | c.57C>A p.D19E | Missense Mutation (SNP) | VAF 53/437 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV54085025; called by muse, mutect2, varscan2
- RYR1 | c.908C>A p.A303D | Missense Mutation (SNP) | VAF 93/744 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1162021667; called by muse, mutect2, varscan2
- SAGE1 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 46/648 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs782250801; called by muse, mutect2
- SBK3 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as rs1282371042; called by muse, mutect2, varscan2
- SCN11A | c.1540G>T p.G514* | Nonsense Mutation (SNP) | VAF 32/339 reads (9%) | catalogued as rs1553638802; called by muse, mutect2
- SCO1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 46/748 reads (6%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs776887702, COSV55135166; called by muse, mutect2
- SLC12A2 | c.2791C>T p.L931F | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.391); catalogued as COSV52471020; called by muse, mutect2
- SLC27A6 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 8/202 reads (4%) | catalogued as COSV52481998, COSV99323514; called by muse, mutect2
- SPEG | c.7024G>A p.E2342K | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs938901169, COSV100403437; called by muse, mutect2
- TRO | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as rs938932098, COSV51496960, COSV99436204; called by muse, mutect2
- TTN | c.72048G>C p.K24016N (on ENST00000591111; = p.K16592N on NM_003319.4) | Missense Mutation (SNP) | VAF 12/154 reads (8%) | PolyPhen possibly damaging (0.693); catalogued as COSV60055376; called by muse, mutect2
- ZFHX4 | c.9724C>T p.Q3242* | Nonsense Mutation (SNP) | VAF 28/430 reads (7%) | catalogued as rs1323855559; called by muse, mutect2
- ABHD16A | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 30/558 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.099); called by muse, mutect2
- AC053503.6 | c.331C>G p.P111A | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated, low confidence (1); called by muse, mutect2
- ACADM | c.833A>T p.D278V | Missense Mutation (SNP) | VAF 76/896 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ALLC | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 31/342 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALPK1 | c.866G>A p.S289N | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ARHGEF17 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- ARHGEF9 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 14/341 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2
- ASPM | c.8880G>T p.K2960N | Missense Mutation (SNP) | VAF 75/882 reads (9%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.971); called by muse, mutect2
- ASTL | c.765G>T p.W255C | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); called by muse, mutect2
- ATP10D | c.1335G>C p.E445D | Missense Mutation (SNP) | VAF 16/446 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CCDC166 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.844); called by muse, mutect2
- CCDC168 | c.20287C>G p.Q6763E | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.112); called by muse, mutect2
- CMTM4 | c.57G>A p.M19I | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); called by muse, mutect2
- COL4A5 | c.4840C>A p.L1614I | Missense Mutation (SNP) | VAF 37/1439 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- CSF1R | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- CST1 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 18/554 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- CTH | c.346+2T>G p.X116_splice | Splice Site (SNP) | VAF 33/800 reads (4%) | called by muse, mutect2
- DAOA | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- DHX30 | c.1694A>G p.D565G (on ENST00000445061 / NM_138615.3; = p.D526G on NM_014966.3) | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DNAJC3 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- E2F5 | c.748A>T p.T250S | Missense Mutation (SNP) | VAF 78/848 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2
- E2F5 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 76/846 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2
- EFCAB13 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 73/312 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- FAM120C | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 17/575 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.812); called by muse, mutect2
- FAT1 | c.7278G>T p.Q2426H | Missense Mutation (SNP) | VAF 49/632 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- FILIP1L | c.1954A>G p.T652A (on ENST00000354552 / NM_182909.3; = p.T412A on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/510 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.083); called by muse, mutect2
- FLNB | c.6847C>T p.P2283S | Missense Mutation (SNP) | VAF 56/383 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- GIMAP1 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 61/448 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- GMPR2 | c.842del p.G281Afs*29 (on ENST00000355299 / NM_001351022.2; = p.G299Afs*29 on NM_016576.5) | Frame Shift Del (DEL) | VAF 31/308 reads (10%) | called by mutect2, pindel, varscan2
- GPHB5 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 28/590 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- GSDME | c.271A>T p.T91S | Missense Mutation (SNP) | VAF 94/954 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- HELT | c.355C>A p.L119I | Missense Mutation (SNP) | VAF 90/663 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- HIKESHI | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 38/740 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.261); called by muse, mutect2
- HUWE1 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 115/1151 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRP1B | c.1236+2T>G p.X412_splice | Splice Site (SNP) | VAF 34/518 reads (7%) | called by muse, mutect2
- MDH1 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 54/1130 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.138); called by muse, mutect2
- MED31 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 17/340 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); called by muse, mutect2
- MEGF6 | c.2655C>G p.I885M | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2
- NHS | c.4061A>T p.K1354M | Missense Mutation (SNP) | VAF 60/463 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- NOP58 | c.483G>A p.M161I | Missense Mutation (SNP) | VAF 22/544 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- NTRK3 | c.2003T>G p.V668G | Missense Mutation (SNP) | VAF 28/698 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- NUDT5 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 21/511 reads (4%) | called by muse, mutect2
- OR10K1 | c.718A>G p.T240A | Missense Mutation (SNP) | VAF 79/1110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR4C15 | c.1006A>T p.N336Y (on ENST00000314644; = p.N282Y on NM_001001920.2) | Missense Mutation (SNP) | VAF 26/762 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR52A5 | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 48/349 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OR52E4 | c.794T>A p.F265Y | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2
- OR8D1 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 60/711 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PADI1 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PCDHAC1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- PCLO | c.898A>T p.S300C | Missense Mutation (SNP) | VAF 114/1144 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2
- PKN2 | c.764C>A p.S255* | Nonsense Mutation (SNP) | VAF 9/221 reads (4%) | called by muse, mutect2
- PLEC | c.5920G>C p.E1974Q (on ENST00000322810 / NM_201380.4; = p.E1864Q on NM_000445.5) | Missense Mutation (SNP) | VAF 13/279 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- PLEC | c.2756C>T p.S919L (on ENST00000322810 / NM_201380.4; = p.S809L on NM_000445.5) | Missense Mutation (SNP) | VAF 18/450 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- POMT2 | c.2240C>T p.S747L | Missense Mutation (SNP) | VAF 21/750 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- RASSF10 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- RFX8 | c.1270C>T p.L424F (on ENST00000646446; = p.L353F on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/664 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.467); called by muse, mutect2
- RIMS2 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 14/365 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RIMS2 | c.865G>A p.D289N (on ENST00000666250 / NM_001348490.2; = p.D97N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/301 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.818); called by muse, mutect2
- RRP1B | c.1500T>A p.S500R | Missense Mutation (SNP) | VAF 44/722 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.147); called by muse, mutect2
- SALL1 | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 45/516 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- SALL1 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.656); called by muse, mutect2
- SCN11A | c.1539T>A p.H513Q | Missense Mutation (SNP) | VAF 31/335 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.231); called by muse, mutect2
- SEC23A | c.2111G>T p.R704I | Missense Mutation (SNP) | VAF 82/998 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- SEPHS2 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 29/562 reads (5%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.082); called by muse, mutect2
- SGIP1 | c.174G>C p.K58N | Missense Mutation (SNP) | VAF 11/288 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); called by muse, mutect2
- SH3BP5L | c.1078C>A p.H360N | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.042); called by muse, mutect2
- SLC39A1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 39/617 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.27); called by muse, mutect2
- SLC40A1 | c.535A>G p.R179G | Missense Mutation (SNP) | VAF 94/922 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SLC4A2 | c.714G>T p.R238S | Missense Mutation (SNP) | VAF 20/478 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2
- SMAD4 | c.1538A>G p.Y513C | Missense Mutation (SNP) | VAF 75/703 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- SNX10 | c.235A>G p.K79E | Missense Mutation (SNP) | VAF 58/414 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- SON | c.5617A>G p.S1873G | Missense Mutation (SNP) | VAF 50/453 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SOX5 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 17/564 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPECC1L | c.2839A>G p.S947G | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SRRM2 | c.6983G>A p.R2328K | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SS18L1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); called by muse, mutect2
- STRIP2 | c.2011C>A p.L671I | Missense Mutation (SNP) | VAF 65/445 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SV2C | c.850A>T p.M284L | Missense Mutation (SNP) | VAF 46/394 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- TMEM168 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); called by muse, mutect2
- TMEM80 | c.122A>T p.Y41F (on ENST00000526170 / NM_001276274.1; = p.Y103F on NM_174940.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TSSK1B | c.867G>C p.E289D | Missense Mutation (SNP) | VAF 18/410 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- TTC39B | c.435A>T p.L145F | Missense Mutation (SNP) | VAF 102/556 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBR4 | c.5780C>T p.S1927F | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- USP11 | c.2497T>A p.Y833N (on ENST00000218348; = p.Y790N on NM_001371072.1) | Missense Mutation (SNP) | VAF 41/443 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- USP17L1 | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 32/595 reads (5%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.942); called by muse, mutect2
- UVSSA | c.1866del p.W622Cfs*6 | Frame Shift Del (DEL) | VAF 62/516 reads (12%) | called by mutect2, pindel, varscan2
- VGLL3 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WIZ | c.3100C>T p.P1034S (on ENST00000673675 / NM_001371589.1; = p.P211S on NM_001330395.4) | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2
- ZGRF1 | c.5067G>A p.W1689* | Nonsense Mutation (SNP) | VAF 36/544 reads (7%) | called by muse, mutect2
- ZNF107 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZNF813 | c.1642G>T p.D548Y | Missense Mutation (SNP) | VAF 100/572 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ABCG1 | c.1608G>A p.L536= | Silent (SNP) | VAF 47/427 reads (11%) | called by muse, mutect2, varscan2
- AC068580.4 | c.19C>T p.L7= | Silent (SNP) | VAF 14/462 reads (3%) | called by muse, mutect2
- ADAMTS16 | c.147G>A p.A49= | Silent (SNP) | VAF 25/603 reads (4%) | catalogued as rs1350979915; called by muse, mutect2
- ATP2B4 | c.2854C>T p.L952= | Silent (SNP) | VAF 28/648 reads (4%) | catalogued as rs1447928109; called by muse, mutect2
- B3GALNT2 | c.750C>T p.L250= | Silent (SNP) | VAF 19/468 reads (4%) | called by muse, mutect2
- BMPR2 | c.2055C>T p.L685= | Silent (SNP) | VAF 45/410 reads (11%) | called by muse, mutect2, varscan2
- CCDC89 | c.939G>C p.R313= | Silent (SNP) | VAF 28/582 reads (5%) | called by muse, mutect2
- CCNB3 | c.1671T>A p.G557= | Silent (SNP) | VAF 18/411 reads (4%) | called by muse, mutect2
- CDC73 | c.187C>T p.L63= | Silent (SNP) | VAF 41/1074 reads (4%) | catalogued as rs779704449; ClinVar: likely benign; called by muse, mutect2
- CHUK | c.78C>T p.F26= | Silent (SNP) | VAF 26/598 reads (4%) | called by muse, mutect2
- E2F2 | c.1188C>T p.C396= | Silent (SNP) | VAF 13/313 reads (4%) | catalogued as COSV62276432; called by muse, mutect2
- EBNA1BP2 | c.87A>T p.R29= | Silent (SNP) | VAF 40/441 reads (9%) | called by muse, mutect2
- EML5 | c.2352G>A p.G784= | Silent (SNP) | VAF 43/760 reads (6%) | called by muse, mutect2
- EVC | c.585G>A p.V195= | Silent (SNP) | VAF 32/738 reads (4%) | catalogued as COSV53830808; called by muse, mutect2
- FAM47A | c.675G>A p.P225= | Silent (SNP) | VAF 59/634 reads (9%) | catalogued as rs776044393, COSV60496205; called by muse, mutect2
- FNDC3B | c.2127G>A p.E709= | Silent (SNP) | VAF 22/362 reads (6%) | called by muse, mutect2
- FPGS | c.1251G>A p.G417= | Silent (SNP) | VAF 36/544 reads (7%) | called by muse, mutect2
- HSPG2 | c.9372G>A p.V3124= | Silent (SNP) | VAF 16/256 reads (6%) | catalogued as rs1477758969; called by muse, mutect2
- KDM5C | c.3306C>T p.L1102= | Silent (SNP) | VAF 38/808 reads (5%) | called by muse, mutect2
- KIAA1549 | c.1809C>T p.F603= | Silent (SNP) | VAF 22/430 reads (5%) | called by muse, mutect2
- KRTAP10-3 | c.153C>T p.S51= | Silent (SNP) | VAF 23/490 reads (5%) | catalogued as rs1480437445; called by muse, mutect2
- MROH2A | c.1272G>A p.R424= | Silent (SNP) | VAF 32/312 reads (10%) | called by muse, mutect2, varscan2
- NICN1 | c.453C>T p.L151= | Silent (SNP) | VAF 17/164 reads (10%) | catalogued as rs1168219699; called by muse, mutect2, varscan2
- OR2A12 | c.126G>A p.G42= | Silent (SNP) | VAF 24/622 reads (4%) | called by muse, mutect2
- PIGG | c.192C>G p.L64= | Silent (SNP) | VAF 58/596 reads (10%) | called by muse, mutect2
- RNF133 | c.711C>G p.L237= | Silent (SNP) | VAF 13/335 reads (4%) | called by muse, mutect2
- RYR2 | c.1258C>A p.R420= | Silent (SNP) | VAF 34/634 reads (5%) | catalogued as rs190140598, CM023669, COSV63663215; called by muse, mutect2
- SCYL2 | c.2169G>C p.L723= | Silent (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- SLC30A9 | c.1386C>T p.L462= | Silent (SNP) | VAF 30/326 reads (9%) | called by muse, mutect2
- SLTM | c.624A>T p.V208= | Silent (SNP) | VAF 24/218 reads (11%) | called by muse, mutect2, varscan2
- SPIRE2 | c.1989T>C p.C663= | Silent (SNP) | VAF 21/542 reads (4%) | called by muse, mutect2
- SYNE2 | c.11745A>G p.S3915= | Silent (SNP) | VAF 34/386 reads (9%) | called by muse, mutect2
- SYNGR1 | c.189C>T p.R63= | Silent (SNP) | VAF 58/625 reads (9%) | called by muse, mutect2
- TBX3 | c.1434C>G p.A478= (on ENST00000257566 / NM_016569.4; = p.A458= on NM_005996.4) | Silent (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- TCF23 | c.249G>T p.A83= | Silent (SNP) | VAF 25/240 reads (10%) | called by muse, mutect2, varscan2
- TMEM132C | c.243G>A p.V81= | Silent (SNP) | VAF 55/543 reads (10%) | called by muse, mutect2, varscan2
- TMEM170B | c.384C>T p.I128= | Silent (SNP) | VAF 25/455 reads (5%) | called by muse, mutect2
- TONSL | c.540G>A p.L180= | Silent (SNP) | VAF 32/476 reads (7%) | called by muse, mutect2
- UNC13A | c.3033C>A p.I1011= | Silent (SNP) | VAF 14/239 reads (6%) | called by muse, mutect2
- VPS45 | c.507G>A p.L169= | Silent (SNP) | VAF 21/414 reads (5%) | called by muse, mutect2
- ZFHX4 | c.870C>T p.I290= | Silent (SNP) | VAF 16/327 reads (5%) | catalogued as COSV51484982; called by muse, mutect2
- ZNF568 | c.1158G>A p.Q386= | Silent (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- CD99 | c.67+394G>T | Intron (SNP) | VAF 19/353 reads (5%) | catalogued as COSV101152920; called by muse, mutect2
- CNOT10 | c.23-8240G>T | Intron (SNP) | VAF 26/412 reads (6%) | called by muse, mutect2
- CPLANE1 | c.*2565A>T | 3'UTR (SNP) | VAF 57/509 reads (11%) | called by muse, mutect2, varscan2
- GABPB1 | c.-1+304C>T | Intron (SNP) | VAF 12/244 reads (5%) | catalogued as rs901272790; called by muse, mutect2
- GPC3 | c.1573+49A>T | Intron (SNP) | VAF 39/420 reads (9%) | called by muse, mutect2
- HOOK1 | c.-62G>C | 5'UTR (SNP) | VAF 20/245 reads (8%) | called by muse, mutect2
- HYPK | c.-73C>T | 5'UTR (SNP) | VAF 75/560 reads (13%) | called by muse, mutect2, varscan2
- KIAA1109 | c.12150+13A>G | Intron (SNP) | VAF 52/558 reads (9%) | called by muse, mutect2
- L1CAM | c.-109+2059_-109+2074del | Intron (DEL) | VAF 26/266 reads (10%) | called by mutect2, pindel
- LAMA1 | c.*28C>T | 3'UTR (SNP) | VAF 68/425 reads (16%) | called by muse, mutect2, varscan2
- OR7E5P | n.261del | RNA (DEL) | VAF 75/620 reads (12%) | called by mutect2, pindel, varscan2
- PPFIA1 | c.1931+2062C>G | Intron (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- PSG5 | c.430+1327G>T | Intron (SNP) | VAF 32/408 reads (8%) | catalogued as COSV61653672; called by muse, mutect2
- SLC12A8 | c.737-151G>A | Intron (SNP) | VAF 32/820 reads (4%) | called by muse, mutect2
- SLC16A7 | c.218-3005G>A | Intron (SNP) | VAF 23/245 reads (9%) | catalogued as rs978281405; called by muse, mutect2, varscan2
- SSX9P | n.282C>T | RNA (SNP) | VAF 78/908 reads (9%) | catalogued as rs782493053; called by muse, mutect2
- TAF1 | c.5002-375G>A | Intron (SNP) | VAF 28/420 reads (7%) | catalogued as rs1308315380; called by muse, mutect2
- UMPS | c.*3482C>T | 3'UTR (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- ZDHHC17 | c.772-1317G>A | Intron (SNP) | VAF 36/363 reads (10%) | called by muse, mutect2
